Somatic mutation profile of tumor specimen TCGA-N1-A6IA-01A (aliquot TCGA-N1-A6IA-01A-12D-A32I-09) from TCGA case TCGA-N1-A6IA, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 41.4 years (15,112 days).
Specimen TCGA-N1-A6IA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa261cac-7bc4-4324-b63d-16837d597cc0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N1-A6IA-11A (Solid Tissue Normal), aliquot TCGA-N1-A6IA-11A-11D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e31d6ea9-1d93-4500-8a8e-55f2e6c29253

The open-access MAF lists 37 somatic variants for this specimen: 30 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 22, Silent 7, Nonsense Mutation 4, Frame Shift Del 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTC1 | c.854T>G p.M285R | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.442); catalogued as COSV99291552; called by muse, mutect2, varscan2
- BCL9 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 18/121 reads (15%) | catalogued as COSV52344444; called by muse, mutect2, varscan2
- BSN | c.10740G>T p.E3580D | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99607052; called by muse, mutect2, varscan2
- CHAF1A | c.2554G>C p.D852H | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100010747; called by muse, mutect2, varscan2
- DAND5 | c.335G>C p.R112P | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as COSV100397174, COSV57683915; called by mutect2, varscan2
- ELN | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as rs782546858, COSV52707520; called by muse, mutect2, varscan2
- FCER1A | c.706A>G p.I236V | Missense Mutation (SNP) | VAF 52/90 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as COSV100929239; called by muse, mutect2, varscan2
- IRF6 | c.196A>T p.K66* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as CM145356, COSV100883841; called by muse, varscan2
- KIF1B | c.2410C>T p.P804S (on ENST00000377086 / NM_001365952.1; = p.P758S on NM_015074.3) | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV55813805; called by muse, mutect2, varscan2
- MACF1 | c.16156G>T p.E5386* (on ENST00000372915; = p.E3319* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | catalogued as COSV99240702; called by muse, mutect2, varscan2
- MYO15A | c.10522C>T p.H3508Y | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.975); catalogued as COSV99230806; called by muse, mutect2, varscan2
- N4BP2 | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99788117; called by muse, mutect2, varscan2
- NTN1 | c.1291G>C p.G431R | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99432095; called by muse, mutect2, varscan2
- NUP133 | c.2042C>G p.S681C | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.552); catalogued as COSV99772484; called by muse, mutect2, varscan2
- OR1E2 | c.147T>G p.I49M | Missense Mutation (SNP) | VAF 88/117 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99943344; called by muse, mutect2, varscan2
- OR7A17 | c.69G>T p.L23F | Missense Mutation (SNP) | VAF 82/98 reads (84%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.405); catalogued as rs1489144290, COSV100541546; called by muse, mutect2, varscan2
- PHRF1 | c.4719G>C p.E1573D (on ENST00000264555 / NM_001286581.2; = p.E1572D on NM_020901.4) | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99199374; called by muse, mutect2, varscan2
- PKHD1L1 | c.8382G>A p.M2794I | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV101005167; called by muse, mutect2, varscan2
- PLXNB3 | c.5672T>A p.L1891Q | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100737045; called by muse, mutect2, varscan2
- PRDM11 | c.64T>A p.C22S | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99770253, COSV99770276; called by muse, mutect2, varscan2
- SLC9A1 | c.1273C>A p.R425S | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99849219; called by muse, mutect2
- TP53 | c.565del p.A189Pfs*58 | Frame Shift Del (DEL) | VAF 58/91 reads (64%) | catalogued as COSV52875466, COSV52908808, COSV53164619; called by mutect2, pindel, varscan2
- UXT | c.407A>C p.H136P | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV99901823; called by muse, mutect2, varscan2
- VDAC1 | c.845A>C p.Q282P | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV99198297; called by muse, mutect2, varscan2
- ZNF2 | c.1237A>G p.T413A (on ENST00000611147 / NM_001291605.2; = p.T400A on NM_021088.4) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV99728198; called by muse, mutect2
- ZNF831 | c.4837A>T p.R1613W | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as COSV100925729; called by muse, mutect2, varscan2
- FAM20A | c.1110-4_1110-3del | Splice Region (DEL) | VAF 32/80 reads (40%) | called by mutect2, pindel, varscan2
- FAM98A | c.572T>G p.L191* | Nonsense Mutation (SNP) | VAF 24/44 reads (55%) | called by muse, mutect2, varscan2
- PNPT1 | c.1466del p.C489Lfs*5 | Frame Shift Del (DEL) | VAF 11/59 reads (19%) | called by mutect2, pindel, varscan2
- SPTBN5 | c.7810_7812del p.L2604del | In Frame Del (DEL) | VAF 24/64 reads (38%) | called by mutect2, pindel, varscan2
- B3GNT3 | c.22C>A p.R8= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV100592611; called by muse, mutect2, varscan2
- CHERP | c.624C>T p.F208= | Silent (SNP) | VAF 155/189 reads (82%) | catalogued as rs762184472, COSV99549909; called by muse, mutect2, varscan2
- FLYWCH1 | c.1398C>G p.T466= (on ENST00000253928 / NM_001308068.2; = p.T465= on NM_020912.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV99558408; called by muse, mutect2
- HTR1E | c.363C>T p.Y121= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs767897205, COSV100540877; called by muse, mutect2, varscan2
- MEFV | c.1297C>T p.L433= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV99560150; called by muse, mutect2, varscan2
- PTK7 | c.3177C>T p.S1059= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs759965386, COSV100029761; called by muse, mutect2, varscan2
- RFC2 | c.690G>A p.R230= (on ENST00000055077 / NM_181471.3; = p.R196= on NM_002914.4) | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV99277680; called by muse, mutect2, varscan2
